Surgical pathology report (de-identified scan), TCGA case TCGA-X6-A7WA, project TCGA-SARC (Sarcoma), tissue source site University of Iowa, specimen TCGA-X6-A7WA-01A (Primary Tumor).

---SURGICAL PATHOLOGY CONSULTATION--- (Accession

Status: Final result

Results

Collection Information

Specimen#	Collection Date	Collection Time	Collected By	Specimen Source	Specimen Description
-----------	-----------------	-----------------	--------------	-----------------	----------------------

Component Results

Component

DIAGNOSIS

Pericardial mass, right, resection:

High grade leiomyosarcoma, 5 cm in greatest dimension, with necrosis and 2-10 mitoses per HPF.

No angiolymphatic invasion identified.

Comment

Date reported:

Pathologist (Electronic Signature)

HISTORY

None provided.

TISSUE SUBMITTED

A. Right pericardial mass

GROSS

Received in saline in a container labeled with the patient's name, hospital number and "Right pericardial mass" is a 5.0 x 4.3 x 3.8 cm mass with an attached 3.2 x 3.0 x 0.2 cm membrane. The mass appears well-circumscribed with a white smooth and glistening lining. The entire specimen is inked blue and is sectioned revealing tan-white, whorled out surfaces that abut the majority of the margin. A portion of the mass is not well-circumscribed and appears to be infiltrating fat adjacent to the mass. This area is 0.2 cm from the surgical margin. Also present is a 1.6 x 1.5 x 1.3 cm red, softened area in the central area of the mass. Representative sections of tumor with area closest to margin submitted in A1-A6.

MICROSCOPIC

Sections demonstrate a hypercellular spindle cell neoplasm arranged in bundled fascicles. The spindle cells demonstrate marked nuclear atypia with bizarre forms and atypical mitotic figures. The mitotic activity is estimated at 2-10 per high power field. The neoplasm demonstrates geographic areas of necrosis. The tumor is strongly positive for desmin and smooth muscle specific actin. The tumor extends to the inked resection margin.

As the primary pathologist on this case, I have personally reviewed this case and edited the report as necessary.

Patient Release Status:

This result is not viewable by the patient.

Lab and Collection

---SURGICAL PATHOLOGY CONSULTATION---

Lab and Collection Information

Result History

---SURGICAL PATHOLOGY CONSULTATION---

Order Result History Report

Result Entered By

Lab information

ICD-O-3
Leiomyosarcoma NOS 8890/3
Site CHEST NOS C49.3
path
Pericardium C38.0
9/10/13

ICD/A Discrepancy		☒

Source: NCI Genomic Data Commons file c8a7b91a-9706-4c7a-992f-f59e8bcd3f1b (TCGA-X6-A7WA.F8D8CB2D-55AC-447D-8C63-802D8E08DE60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).